Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A3XC, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A3XC-01A (Primary Tumor).

Procurement Date: Laterality:

Path Report: SKIN TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Skin

Tumor size: 2 x 1.5 x 0.4 cm

Tumor features: Ulcerated, Raised

Satellite nodules: Not specified

Histologic type: Nodular melanoma

Histologic grade:

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: IV level 6.0 mm deep

ICD-O-3

CQCF: melanoma, NOS
8720/3

Path: melanoma, nodular
8721/3

Site: Skin, NOS
C44.9

5-17-12
KO

Source: NCI Genomic Data Commons file 2aa74c33-272f-427c-8ff1-3592a03aede2 (TCGA-EB-A3XC.F2263A67-85EC-4478-BFCD-56C8BE4874DC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).